Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8380, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8380-01A (Primary Tumor).

[page 1 of 2]
Patient ID:

Surgical Date:

Gross Description: Dissected part of the stomach with greater and lesser omentum;

along the lesser curvature - 13cm, along the greater curvature - 20cm;

in the antral part there is a circular tumour 9 cm long; (while opened 9 x 9 x 1.5 cm), wall is diffusely densed, thickened up to 1.5 cm; greater and lesser omentum lymph nodes are 0.2 -1.5 cm in their diameter (fifteen)

Microscopic Description: Poorly differentiated adenocarcinoma of the stomach with all wall layers and omentum tissues invasion; distal part of the surgical margins and lymphatic vessels contain tumor elements; fifteen lymph nodes were examined, eleven demonstrated metastases.

Diagnosis Details: Tumor Features: Diffusely infiltrating (linitus plastic), Tumor Extent: Perigastric fat , Venous Invasion: Absent, Margins: Present, Treatment Effect:

Comments:

Formatted Path Reports: STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy

Tumor site: Antrum

Tumor size: 9 x 1.5 x 9 cm

Tumor features: Diffusely infiltrating (linitus plastica)

Histologic type: Adenocarcinoma

Histologic grade: Poorly differentiated

Tumor extent: Serosa (visceral peritoneum)

Lymph nodes: 11/15 positive for metastasis (Greater and lesser curvature 11/15)

Lymphatic invasion: Not specified

Venous invasion: Absent

Perineural invasion: Not specified

Margins: Involved

ICA - 0-3

adenocarcinoma, NOS 8140/3

site: antrum c 16.3

11/5/13

[page 2 of 2]
Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Major Malignancy History		✓
Qual/Sync/Cont: Primary Noted		
reviewed Initial	11/5/13	11/5/13

Source: NCI Genomic Data Commons file f1038d31-5261-491f-9212-3a48e4736717 (TCGA-BR-8380.7D2AF5C0-EA38-422F-83F7-EF1812BEE118.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).